TARGET case TARGET-15-SJMPAL011912 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0a3ce7da-507d-4c2d-b02e-39b0d88300ca

Demographics
Sex at birth: male; Age at index: 12 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 12.0 years (4,386 days); Year of diagnosis: 2005; Days to last follow up: 3,161 days (8.7 years).

Follow-up (1 entry)
- Days to follow up: 3,161 days (8.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,161; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 4.2 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL011912-09A, TARGET-15-SJMPAL011912-09A.1 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL011912-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 3161
- Protocol: St. Jude
- WBC at Diagnosis: 4.2
- Initial Therapy: AML
- Karyotype: 46,XY[20]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
